Somatic mutation profile of tumor specimen ALCH-AERJ-TTP1-A (aliquot ALCH-AERJ-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AERJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.5 years (21,735 days).
Specimen ALCH-AERJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a3991fc-ed49-4aee-b841-e974864a706e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AERJ-NB1-A (Blood Derived Normal), aliquot ALCH-AERJ-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/001bba13-5739-45b9-a55e-cd47495abb29

The open-access MAF lists 239 somatic variants for this specimen: 158 protein-altering or splice-affecting, 47 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 47, Intron 12, RNA 11, Nonsense Mutation 10, 5'UTR 6, Splice Site 3, 5'Flank 2, Frame Shift Del 2, 3'Flank 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 70/369 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ABCG2 | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as COSV52946359; called by muse, varscan2
- AFDN | c.4213G>T p.A1405S | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.188); catalogued as rs1360442270; called by muse, mutect2
- ATG7 | c.1093A>T p.T365S | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752312023; called by muse, mutect2, varscan2
- CA1 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 109/654 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810303; called by muse, mutect2, varscan2
- CCPG1 | c.98C>G p.T33S | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs181640191; called by muse, mutect2, varscan2
- CGB2 | c.12G>T p.G4= | Splice Region (SNP) | VAF 11/376 reads (3%) | catalogued as rs1275000963; called by muse, mutect2
- CHEK2 | c.1142T>G p.L381R (on ENST00000382580 / NM_001005735.2; = p.L338R on NM_007194.4) | Missense Mutation (SNP) | VAF 87/610 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374660293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL24A1 | c.2038C>A p.P680T | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as COSV65305204; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54743444; called by muse, mutect2, varscan2
- DCAF4L2 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 60/479 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1413757500, COSV100151059; called by muse, mutect2, varscan2
- DLGAP1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs995706290; called by muse, mutect2, varscan2
- DNAH8 | c.10771C>A p.Q3591K | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544004; called by muse, mutect2, varscan2
- ERGIC3 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 32/434 reads (7%) | catalogued as rs769257293, COSV99481796; called by muse, mutect2
- FBXO25 | c.916C>A p.H306N (on ENST00000382824 / NM_183421.2; = p.H239N on NM_012173.3) | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.293); catalogued as rs766478103; called by muse, mutect2
- FOCAD | c.2522A>G p.Y841C | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146757351; called by muse, varscan2
- GREB1 | c.2908G>T p.V970L | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs367624603, COSV52190269; called by muse, mutect2, varscan2
- IPO9 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.289); catalogued as COSV99819495; called by muse, mutect2, varscan2
- ITGB8 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252177451; called by muse, mutect2, varscan2
- LINGO3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV68261050; called by muse, mutect2, varscan2
- MAFB | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.144); catalogued as COSV64826990; called by muse, mutect2
- MPP7 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV61730905; called by muse, mutect2, varscan2
- MRGPRD | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1459967305; called by muse, mutect2, varscan2
- MYOF | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as rs1220993155; called by muse, mutect2, varscan2
- NEB | c.10312G>A p.V3438M | Missense Mutation (SNP) | VAF 80/748 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs751223917; called by muse, varscan2
- NF1 | c.4868T>G p.L1623R (on ENST00000358273 / NM_001042492.3; = p.L1602R on NM_000267.3) | Missense Mutation (SNP) | VAF 103/376 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD1415183, CM086304; called by muse, mutect2, varscan2
- NSUN2 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs377501138; called by muse, mutect2
- PCDH15 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 55/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57372502, COSV57380811, COSV57404150; called by muse, mutect2, varscan2
- PCDH15 | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV57380838; called by muse, mutect2, varscan2
- PCDH15 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as rs769261753; called by muse, mutect2, varscan2
- PDE2A | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57803794; called by muse, mutect2, varscan2
- PDGFRA | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.824); catalogued as COSV57270773; called by muse, mutect2, varscan2
- PEX5L | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99829180; called by muse, mutect2, varscan2
- PPME1 | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972443191; called by muse, mutect2, varscan2
- PRAMEF11 | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 84/737 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101463229; called by muse, mutect2, varscan2
- RASA1 | c.2514del p.N838Kfs*4 | Frame Shift Del (DEL) | VAF 40/347 reads (12%) | catalogued as COSV99169629; called by mutect2, pindel, varscan2
- RTEL1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs201555555, COSV58896001; called by muse, varscan2
- RYR2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV63695628; called by muse, mutect2
- RYR2 | c.11890C>A p.Q3964K | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63685118; called by muse, mutect2, varscan2
- RYR3 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101211710; called by muse, mutect2, varscan2
- SLFN11 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1229291682, COSV57697698; called by muse, mutect2, varscan2
- SOBP | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179582290; called by muse, mutect2, varscan2
- SPEG | c.7984G>A p.V2662I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs374618068; called by muse, mutect2, varscan2
- TBCA | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs774505435; called by muse, mutect2
- TGFBR1 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 112/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120557, COSV66625366; called by muse, mutect2, varscan2
- TMEM132B | c.3214G>T p.E1072* | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | catalogued as COSV54745149; called by muse, mutect2, varscan2
- TRIML1 | c.824C>G p.T275R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs745539786, COSV60194468; called by muse, mutect2, varscan2
- TTK | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 50/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036622, COSV57886829; called by muse, mutect2, varscan2
- UBQLN3 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs570150468; called by muse, mutect2, varscan2
- VMAC | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751669540, COSV100258937; called by muse, mutect2, varscan2
- ABCA13 | c.9728A>T p.Q3243L | Missense Mutation (SNP) | VAF 80/535 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.12871C>G p.Q4291E | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADSS2 | c.1089G>T p.L363F | Missense Mutation (SNP) | VAF 52/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFMID | c.886-1G>T p.X296_splice | Splice Site (SNP) | VAF 38/678 reads (6%) | called by muse, mutect2
- AGRN | c.3550A>G p.K1184E | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ANKK1 | c.861A>G p.I287M | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.12649T>C p.C4217R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ARID4A | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BCL3 | c.632_646del p.L211_H215del | In Frame Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- BPI | c.1160T>C p.F387S (on ENST00000262865; = p.F383S on NM_001725.3) | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTAF1 | c.443T>C p.L148S | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C1orf131 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 56/461 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- C2orf42 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CADPS | c.3704C>T p.T1235I | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); called by muse, mutect2
- CAPRIN2 | c.2356G>T p.G786C | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CATSPERG | c.1647G>T p.Q549H | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CBFA2T3 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- CDC42BPG | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 110/550 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEL | c.857C>T p.P286L (on ENST00000673714; = p.P283L on NM_001807.6) | Missense Mutation (SNP) | VAF 98/427 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CEP192 | c.6557A>C p.E2186A | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- CFHR5 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 61/533 reads (11%) | called by muse, mutect2, varscan2
- COL24A1 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- COL26A1 | c.620C>A p.T207K (on ENST00000313669 / NM_001278563.3; = p.T205K on NM_133457.4) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CRYBB1 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRYBG3 | c.4042A>T p.S1348C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- DNAH5 | c.5883-2A>G p.X1961_splice | Splice Site (SNP) | VAF 69/654 reads (11%) | called by muse, mutect2
- DTNB | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 55/435 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EEF1B2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ERICH3 | c.438A>T p.L146F | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FAIM2 | c.528C>A p.T176= | Splice Region (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- FAM71B | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- FANCM | c.967A>G p.R323G | Missense Mutation (SNP) | VAF 123/527 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FBXW7 | c.1702G>T p.V568L (on ENST00000281708 / NM_001349798.2; = p.V488L on NM_018315.5) | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- FRMD7 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSHR | c.1992C>G p.N664K | Missense Mutation (SNP) | VAF 87/641 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FTH1 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GCAT | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- GMCL1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- GOLGA8K | c.1366A>T p.S456C | Missense Mutation (SNP) | VAF 41/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- GPAT2 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRAP2 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- GRIN2B | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 126/824 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HERC1 | c.9151A>G p.K3051E | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.287); called by muse, varscan2
- HOXC10 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IFI44L | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- IFI44L | c.1324+1G>T p.X442_splice | Splice Site (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 181/549 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- IGKV2D-30 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 55/402 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by mutect2, varscan2
- IGLV1-36 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- IL18R1 | c.340A>G p.R114G | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ITM2A | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- KCNK15 | c.897C>A p.C299* | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- KMT2D | c.8776del p.V2926Yfs*17 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- LAMB4 | c.3277G>T p.D1093Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- LRP1B | c.10255C>T p.Q3419* | Nonsense Mutation (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- LRP1B | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRTM2 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MMP16 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2
- MMRN1 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A4E | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MUC12 | c.1640C>T p.T547I (on ENST00000379442; = p.T404I on NM_001164462.1) | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- NFATC1 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 45/228 reads (20%) | called by muse, mutect2, varscan2
- NFATC2IP | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- NKX3-2 | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NRK | c.3584C>A p.A1195E | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR51E2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 62/464 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- PARVB | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 59/407 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PCDHAC1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 56/282 reads (20%) | called by muse, mutect2, varscan2
- PDGFC | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 88/527 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PLXNA4 | c.1766C>A p.A589D | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PNLDC1 | c.962G>T p.S321I | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- POLQ | c.3160A>G p.S1054G | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAME | c.582C>G p.Y194* | Nonsense Mutation (SNP) | VAF 89/565 reads (16%) | called by muse, mutect2, varscan2
- PREX2 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 65/579 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PRKACG | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRN2 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 46/203 reads (23%) | called by mutect2, varscan2
- PYM1 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPH3A | c.1738A>T p.M580L (on ENST00000389385 / NM_001143854.2; = p.M576L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- RYR1 | c.7094G>T p.G2365V | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- RYR2 | c.12778A>C p.S4260R | Missense Mutation (SNP) | VAF 137/1304 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SEC61A1 | c.864C>A p.N288K | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEM1 | c.51C>A p.D17E | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SLC6A12 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLIT3 | c.1972A>T p.I658L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLITRK2 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPOCK3 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPP1 | c.20G>T p.C7F | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SWSAP1 | c.563G>T p.G188V (on ENST00000312423; = p.G209V on NM_175871.4) | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SYNE1 | c.15951G>T p.L5317F (on ENST00000367255 / NM_182961.4; = p.L5246F on NM_033071.3) | Missense Mutation (SNP) | VAF 69/541 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TBATA | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 77/522 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TESPA1 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TNKS1BP1 | c.3994C>G p.Q1332E | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNN | c.3132T>G p.F1044L | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TNR | c.2972C>A p.A991E | Missense Mutation (SNP) | VAF 111/508 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- TNR | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNRC18 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TRIM49 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRMT10B | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 88/388 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.47713G>C p.A15905P (on ENST00000591111; = p.A8481P on NM_003319.4) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBB2A | c.820A>T p.T274S | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.173); called by muse, varscan2
- UBQLN3 | c.293T>A p.M98K | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A7 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 91/615 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ULK1 | c.1765C>A p.P589T | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZDHHC17 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ZDHHC6 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFR2 | c.1833G>T p.Q611H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZIC3 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF560 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ACP4 | c.285G>A p.P95= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs185153035; called by muse, mutect2, varscan2
- AFDN | c.4158G>A p.L1386= | Silent (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- AGA | c.906G>T p.G302= | Silent (SNP) | VAF 91/576 reads (16%) | catalogued as COSV99219717; called by muse, mutect2, varscan2
- CD163 | c.1224T>C p.D408= | Silent (SNP) | VAF 90/677 reads (13%) | called by muse, mutect2, varscan2
- CHI3L1 | c.987C>T p.D329= | Silent (SNP) | VAF 73/512 reads (14%) | catalogued as rs1405592328; called by muse, mutect2, varscan2
- CHIA | c.1245C>T p.S415= (on ENST00000343320; = p.S307= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as rs761599968, COSV58473662; called by muse, mutect2, varscan2
- CR1L | c.927A>C p.S309= | Silent (SNP) | VAF 169/770 reads (22%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.312T>C p.A104= | Silent (SNP) | VAF 60/306 reads (20%) | called by muse, mutect2, varscan2
- CTSB | c.102C>A p.V34= | Silent (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- EHHADH | c.1152G>A p.E384= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- EPB41L3 | c.1551C>A p.S517= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as COSV59446007; called by muse, mutect2, varscan2
- FGF9 | c.525G>C p.G175= | Silent (SNP) | VAF 103/591 reads (17%) | called by muse, mutect2, varscan2
- GFI1B | c.387C>A p.A129= | Silent (SNP) | VAF 100/378 reads (26%) | called by muse, mutect2, varscan2
- GUCY2D | c.1560T>G p.S520= | Silent (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- KCNC2 | c.666C>G p.P222= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- KCNJ14 | c.1203G>A p.E401= | Silent (SNP) | VAF 40/308 reads (13%) | called by muse, mutect2, varscan2
- LIMS2 | c.540G>T p.L180= (on ENST00000355119 / NM_001161403.3; = p.L204= on NM_017980.4) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55757410; called by muse, mutect2, varscan2
- LPAR4 | c.780A>T p.V260= | Silent (SNP) | VAF 70/166 reads (42%) | called by muse, mutect2, varscan2
- LRMDA | c.271C>T p.L91= | Silent (SNP) | VAF 29/208 reads (14%) | called by muse, mutect2
- LRRTM4 | c.1260T>C p.V420= | Silent (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- MMD2 | c.207C>A p.A69= | Silent (SNP) | VAF 61/370 reads (16%) | catalogued as COSV101287149; called by muse, mutect2, varscan2
- MNX1 | c.60C>A p.A20= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- NF1 | c.4869G>T p.L1623= (on ENST00000358273 / NM_001042492.3; = p.L1602= on NM_000267.3) | Silent (SNP) | VAF 105/376 reads (28%) | catalogued as COSV55985858; called by muse, mutect2, varscan2
- NFATC1 | c.1551G>T p.L517= | Silent (SNP) | VAF 45/233 reads (19%) | called by muse, mutect2, varscan2
- NKD2 | c.978G>A p.P326= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs757349671, COSV56890646; called by mutect2, varscan2
- NUTM1 | c.3288C>G p.V1096= | Silent (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.15492G>A p.K5164= | Silent (SNP) | VAF 28/568 reads (5%) | called by muse, mutect2
- OR5H1 | c.633T>C p.I211= | Silent (SNP) | VAF 89/590 reads (15%) | catalogued as rs1331412228, COSV63402325; called by muse, mutect2, varscan2
- P2RX1 | c.291C>T p.D97= | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, varscan2
- PLEC | c.6757C>A p.R2253= (on ENST00000322810 / NM_201380.4; = p.R2143= on NM_000445.5) | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- POPDC2 | c.420G>A p.L140= | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- POPDC3 | c.147G>T p.G49= | Silent (SNP) | VAF 67/459 reads (15%) | called by muse, mutect2, varscan2
- POTEF | c.2667C>G p.L889= | Silent (SNP) | VAF 75/405 reads (19%) | called by muse, mutect2, varscan2
- PPP1R21 | c.798T>C p.L266= | Silent (SNP) | VAF 42/359 reads (12%) | called by muse, mutect2, varscan2
- PRDM9 | c.1374A>G p.E458= | Silent (SNP) | VAF 93/947 reads (10%) | called by muse, mutect2, varscan2
- PRRT4 | c.1680G>T p.T560= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101435726; called by muse, mutect2, varscan2
- RBPJL | c.792G>A p.P264= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as rs762271907, COSV59212487; called by muse, varscan2
- RNF148 | c.183G>T p.V61= | Silent (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- SACS | c.6348C>T p.P2116= | Silent (SNP) | VAF 44/287 reads (15%) | catalogued as rs375619621; called by muse, mutect2, varscan2
- SLC46A2 | c.936T>A p.P312= | Silent (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- SPAM1 | c.897G>A p.P299= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV56144167; called by muse, mutect2, varscan2
- STARD8 | c.1947G>T p.R649= | Silent (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2, varscan2
- TIMM44 | c.1308G>C p.A436= | Silent (SNP) | VAF 79/431 reads (18%) | called by muse, mutect2, varscan2
- TRPC5 | c.2604T>C p.S868= | Silent (SNP) | VAF 61/156 reads (39%) | called by muse, mutect2, varscan2
- TRPV6 | c.351C>T p.A117= | Silent (SNP) | VAF 20/229 reads (9%) | catalogued as COSV63891896; called by muse, mutect2
- UNC5D | c.2412C>T p.C804= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- ZEB2 | c.426A>C p.S142= | Silent (SNP) | VAF 59/552 reads (11%) | called by muse, mutect2, varscan2
- AC005008.2 | n.157del | RNA (DEL) | VAF 33/291 reads (11%) | called by mutect2, pindel, varscan2
- ACBD5 | chr10:27196954 G>A | 3'Flank (SNP) | VAF 57/466 reads (12%) | catalogued as rs1564539899; called by muse, mutect2, varscan2
- AGAP14P | n.403A>T | RNA (SNP) | VAF 28/248 reads (11%) | called by mutect2, varscan2
- AKAP14 | c.261+21C>A | Intron (SNP) | VAF 112/260 reads (43%) | called by muse, mutect2, varscan2
- ASPH | c.322+4829G>T | Intron (SNP) | VAF 101/564 reads (18%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+479G>T | Intron (SNP) | VAF 106/438 reads (24%) | called by muse, mutect2, varscan2
- CALCR | c.-65del | 5'UTR (DEL) | VAF 23/224 reads (10%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.-7T>A | 5'UTR (SNP) | VAF 59/354 reads (17%) | called by muse, mutect2, varscan2
- CCNQP1 | n.164G>C | RNA (SNP) | VAF 68/413 reads (16%) | called by muse, mutect2, varscan2
- CD28 | chr2:203706563 G>T | 5'Flank (SNP) | VAF 67/449 reads (15%) | called by muse, mutect2, varscan2
- CFAP157 | c.*1823A>T | 3'UTR (SNP) | VAF 43/196 reads (22%) | called by muse, mutect2, varscan2
- CLEC17A | c.-24C>A | 5'UTR (SNP) | VAF 28/175 reads (16%) | catalogued as COSV100355292; called by muse, mutect2, varscan2
- CLVS1 | c.-152+4265G>A | Intron (SNP) | VAF 53/297 reads (18%) | called by muse, mutect2, varscan2
- DRAP1 | c.-50G>T | 5'UTR (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- FAM221A | c.239+1648G>T | Intron (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- FSTL1 | c.331+83C>G | Intron (SNP) | VAF 70/559 reads (13%) | called by muse, mutect2, varscan2
- GVINP1 | n.3575del | RNA (DEL) | VAF 29/234 reads (12%) | called by mutect2, pindel, varscan2
- HLA-V | n.4234A>T | RNA (SNP) | VAF 59/277 reads (21%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.124C>A | RNA (SNP) | VAF 56/582 reads (10%) | called by muse, mutect2
- HTR3A | c.68-256C>G | Intron (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- LEUTX | c.-110C>A | 5'UTR (SNP) | VAF 57/371 reads (15%) | called by muse, mutect2, varscan2
- LINC02448 | n.336C>T | RNA (SNP) | VAF 55/418 reads (13%) | catalogued as rs761496071; called by muse, mutect2, varscan2
- LPXN | chr11:58578056 C>A | 5'Flank (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- MEIOB | c.1218+1404T>A | Intron (SNP) | VAF 35/193 reads (18%) | called by muse, mutect2, varscan2
- MIR519C | n.78C>T | RNA (SNP) | VAF 18/156 reads (12%) | catalogued as rs1330096674; called by muse, varscan2
- NEBL | c.164+46335G>A | Intron (SNP) | VAF 42/309 reads (14%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31343G>C | Intron (SNP) | VAF 93/575 reads (16%) | called by muse, mutect2, varscan2
- OPN4 | chr10:86666822 G>C | 3'Flank (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- SLC35G6 | c.-38T>C | 5'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs1304789732; called by muse, mutect2, varscan2
- SNURFL | n.90G>T | RNA (SNP) | VAF 49/108 reads (45%) | called by muse, varscan2
- TBC1D3P2 | n.464G>A | RNA (SNP) | VAF 151/576 reads (26%) | called by muse, mutect2, varscan2
- TMEM78 | n.370G>T | RNA (SNP) | VAF 62/252 reads (25%) | called by muse, varscan2
- TRIM67 | c.1045-12264G>T | Intron (SNP) | VAF 75/600 reads (13%) | called by muse, mutect2, varscan2
- UACA | c.78+14171A>G | Intron (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
